Somatic mutation profile of tumor specimen TCGA-KK-A8IG-01A (aliquot TCGA-KK-A8IG-01A-11D-A364-08) from TCGA case TCGA-KK-A8IG, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.5 years (20,266 days).
Specimen TCGA-KK-A8IG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 569f33ae-c717-4bb0-b2b5-6a0cf6490b9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IG-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IG-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8329023-7a95-4be0-9db4-1c97ddc61209

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100719445; called by muse, mutect2, varscan2
- ALX1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV57492068; called by muse, mutect2, varscan2
- AP3B2 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751006728, COSV55609858, COSV99916151; called by muse, mutect2, varscan2
- ARHGAP32 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1218917564, COSV100089715; called by muse, mutect2, varscan2
- ARHGAP5 | c.2277C>A p.H759Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as COSV100565746; called by muse, mutect2, varscan2
- CD180 | c.908T>C p.L303S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842457; called by muse, mutect2, varscan2
- DOP1A | c.5354C>A p.S1785* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99383139; called by muse, mutect2
- JADE1 | c.1114A>T p.R372W | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99886423; called by muse, mutect2
- KBTBD3 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1306786267, COSV101595736; called by muse, mutect2, varscan2
- LRRC66 | c.2423C>G p.S808* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100603140; called by muse, mutect2
- METTL14 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.058); catalogued as COSV101183431; called by muse, mutect2, varscan2
- OTOP2 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 136/275 reads (49%) | catalogued as COSV100509044; called by muse, mutect2, varscan2
- PNPLA7 | c.24C>G p.S8R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as COSV99481702; called by muse, mutect2, varscan2
- PTRHD1 | c.381A>C p.E127D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.751); catalogued as COSV99579367; called by muse, mutect2, varscan2
- SLC25A38 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV99827967; called by muse, mutect2, varscan2
- SSTR1 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs199603499, COSV99943234; called by muse, mutect2, varscan2
- TACC2 | c.2774G>T p.S925I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100554362; called by muse, mutect2, varscan2
- ZBED1 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs751355986, COSV100586164; called by muse, mutect2
- ZNF518A | c.1393C>G p.Q465E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100283792; called by muse, mutect2, varscan2
- ZNF793 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs200037315; called by muse, mutect2, varscan2
- ATM | c.2093_2094del p.S698* | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- FOXA1 | c.782_786dup p.Q263Afs*60 | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- NEURL4 | c.3688T>C p.C1230R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2
- COL24A1 | c.2247A>C p.S749= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100994181; called by muse, mutect2, varscan2
- EPHB2 | c.1500C>T p.A500= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs775705074, COSV65864318; called by muse, mutect2, varscan2
- NCCRP1 | c.606G>A p.A202= | Silent (SNP) | VAF 12/177 reads (7%) | catalogued as rs1213916230, COSV100355910; called by muse, mutect2
- SLC4A1AP | c.1899A>G p.E633= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100389723; called by muse, mutect2
- THY1 | c.21C>T p.I7= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs762262836, COSV99411619; called by muse, mutect2, varscan2
- TMEM248 | c.555C>T p.C185= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100447396; called by muse, mutect2
- TOP1 | c.807T>C p.T269= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV100793993; called by muse, mutect2, varscan2
- WDR73 | c.433T>C p.L145= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100822128; called by muse, mutect2, varscan2
